Somatic mutation profile of tumor specimen TCGA-B6-A0I2-01A (aliquot TCGA-B6-A0I2-01A-11W-A050-09) from TCGA case TCGA-B6-A0I2, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 45.7 years (16,702 days).
Specimen TCGA-B6-A0I2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8e61ed1-3f93-4e8e-940b-7623d1744453.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0I2-10A (Blood Derived Normal), aliquot TCGA-B6-A0I2-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3abd87d-8040-4db5-a537-c5729b235d26

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 39, Silent 11, Nonsense Mutation 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR3B | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs771304758, COSV55450969; called by muse, mutect2, varscan2
- ADCK1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 23/43 reads (53%) | catalogued as rs142770287; called by muse, mutect2, varscan2
- API5 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV66633922; called by muse, mutect2, varscan2
- ARCN1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99873454, COSV99873636; called by muse, mutect2
- CACNA1F | c.3421C>T p.R1141C | Missense Mutation (SNP) | VAF 180/424 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1557107139, COSV59905430, COSV99058909; called by muse, mutect2, varscan2
- CCDC33 | c.1247A>G p.E416G | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV58354138; called by muse, mutect2, varscan2
- CDC37 | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55768951; called by muse, mutect2, varscan2
- CNN3 | c.185T>G p.I62R | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV64637028; called by muse, mutect2, varscan2
- CNTNAP5 | c.3154C>A p.L1052I | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as COSV70495018; called by muse, mutect2, varscan2
- COLEC11 | c.412T>G p.F138V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99363163; called by muse, mutect2
- CPAMD8 | c.3248G>C p.R1083T (on ENST00000651564; = p.R1036T on NM_015692.5) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV71596828; called by muse, varscan2
- DCC | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 95/240 reads (40%) | catalogued as COSV59115235, COSV59135259; called by muse, mutect2, varscan2
- ENOX1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV54906483; called by muse, mutect2, varscan2
- GMFG | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV53419448; called by muse, mutect2, varscan2
- ICE1 | c.3869T>G p.V1290G | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV56828244; called by muse, mutect2, varscan2
- IFNAR1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 112/349 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54252797; called by muse, mutect2, varscan2
- IGF2BP1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as COSV51733249; called by muse, mutect2, varscan2
- KCTD21 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 68/473 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60741110, COSV60741428; called by muse, mutect2, varscan2
- KIF27 | c.2002C>G p.Q668E | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV52829274; called by muse, mutect2, varscan2
- KNL1 | c.6516G>C p.K2172N (on ENST00000346991 / NM_170589.5; = p.K2146N on NM_144508.5) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.063); catalogued as COSV61157119; called by muse, mutect2, varscan2
- LZTR1 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs757502214, COSV53148921; called by muse, mutect2, varscan2
- MAP7D2 | c.1509G>A p.M503I | Missense Mutation (SNP) | VAF 38/1175 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as COSV101107318; called by muse, mutect2
- MARK2 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 61/178 reads (34%) | catalogued as COSV59285642; called by muse, mutect2, varscan2
- MIB1 | c.2305C>T p.R769* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | catalogued as rs752243957, COSV55092285; called by muse, mutect2, varscan2
- MRPS7 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55453856; called by mutect2, varscan2
- MYO10 | c.5470G>C p.E1824Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57025164; called by muse, mutect2, varscan2
- PPP1R17 | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 96/362 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.714); catalogued as COSV59611909; called by muse, mutect2, varscan2
- PRB2 | c.379A>T p.N127Y | Missense Mutation (SNP) | VAF 276/1951 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV66983634; called by muse, mutect2, varscan2
- PRICKLE3 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV66235070; called by muse, mutect2, varscan2
- PRKD1 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 40/224 reads (18%) | catalogued as COSV59562884, COSV59575810; called by muse, mutect2, varscan2
- QTRT2 | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV99846879; called by muse, mutect2
- R3HDML | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777264582, COSV53836840; called by muse, mutect2, varscan2
- RARG | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754842832, COSV58433586; called by muse, mutect2, varscan2
- RNASEH2A | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV55552279; called by muse, mutect2, varscan2
- SAGE1 | c.491T>C p.M164T | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as COSV100187073; called by muse, mutect2
- SF3B1 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV59219482; called by muse, mutect2, varscan2
- SLC1A6 | c.798C>G p.I266M | Missense Mutation (SNP) | VAF 10/313 reads (3%) | SIFT tolerated (0.87); PolyPhen benign (0.029); catalogued as COSV99693655; called by muse, mutect2
- SLC25A18 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs760504564, COSV53658882; called by muse, mutect2, varscan2
- SMARCA2 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 385/887 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV61809635; called by muse, mutect2, varscan2
- SMYD3 | c.620G>T p.S207I (on ENST00000490107 / NM_001375962.1; = p.S148I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV63627785; called by muse, mutect2, varscan2
- ZBED9 | c.2863G>A p.V955I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV101509216; called by muse, mutect2, varscan2
- ZNF425 | c.1030G>C p.G344R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.1); catalogued as COSV65201796; called by muse, mutect2, varscan2
- ATRAID | c.369G>C p.Q123H (on ENST00000611786; = p.Q10H on NM_016085.5) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); called by muse, mutect2
- CDCA8 | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TP53 | c.479_483dup p.I162Wfs*10 | Frame Shift Ins (INS) | VAF 38/110 reads (35%) | called by mutect2, pindel, varscan2
- ASAP3 | c.2259G>T p.P753= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV60875935, COSV60877732; called by muse, mutect2, varscan2
- ATP11C | c.234C>T p.I78= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV59568037; called by muse, mutect2, varscan2
- CSMD1 | c.792C>T p.I264= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs756317521, COSV101219612; called by muse, mutect2, varscan2
- DKK3 | c.381C>G p.V127= | Silent (SNP) | VAF 570/679 reads (84%) | catalogued as COSV58869288; called by muse, mutect2, varscan2
- ELF4 | c.105G>A p.V35= | Silent (SNP) | VAF 4/100 reads (4%) | catalogued as rs1366623399, COSV100257322; called by muse, mutect2
- H4C7 | c.132C>G p.V44= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs201443702, COSV55100318; called by muse, mutect2, varscan2
- LRP1 | c.3357C>A p.I1119= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV54517130, COSV99676324; called by muse, mutect2, varscan2
- NMRAL1 | c.834C>G p.L278= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV52060460; called by muse, mutect2, varscan2
- RFLNB | c.150C>T p.D50= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1280117741, COSV61239210; called by muse, mutect2, varscan2
- SLC8A3 | c.2160G>T p.G720= (on ENST00000381269 / NM_183002.3; = p.G718= on NM_033262.4) | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV53690877, COSV53692882; called by muse, mutect2, varscan2
- UBA2 | c.1044C>T p.D348= | Silent (SNP) | VAF 9/230 reads (4%) | catalogued as COSV99875450; called by muse, mutect2
